Gene-level copy-number profile of tumor specimen TCGA-13-0893-01B from TCGA case TCGA-13-0893, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.1 years (17,573 days).
Specimen TCGA-13-0893-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1062384d-2437-4f50-9f5f-ec5630d1b710.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0893-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fab60e8-29d3-4db9-accb-b3e912f364e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,879; copy number 2: 17,591; copy number 3: 22,799; copy number 4: 9,174; copy number 5: 5,584; copy number 6: 892; copy number 7: 840; copy number 8: 128; copy number 9: 423; copy number 10: 131; copy number 12: 371.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0893-01B-01D-0452-01): tumor purity 0.71, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:240,713,761–240,824,293, 1 gene: KIF1A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,893 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:63,440,770–63,593,721, 1 gene, copy number 7 (within-gene range 4–7): ITGB3BP.
- chr1:63,523,372–65,092,614, 35 genes, copy number 7: EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1.
- chr1:86,571,181–87,109,982, 9 genes, copy number 7 (within-gene range 4–7): CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, AL355981.1, SELENOF, HS2ST1, AL121989.1.
- chr1:87,044,935–87,046,700, 2 genes, copy number 7: AC093155.2, AC093155.1.
- chr1:150,045,660–152,115,454, 118 genes, copy number 7 (broad region; genes not listed).
- chr3:58,008,400–58,330,118, 9 genes, copy number 7: FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1.
- chr3:137,791,973–138,834,928, 21 genes, copy number 7: AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25.
- chr3:141,470,634–151,928,175, 184 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr3:164,670,878–169,663,775, 52 genes, copy number 7 (within-gene range 5–7): LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1.
- chr5:58,198–20,575,873, 357 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:84,528,122–85,489,293, 11 genes, copy number 8: RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972.
- chr8:82,033,533–145,066,685, 980 genes, copy number 8–12 (broad region; genes not listed).
- chr9:124,942,608–125,143,528, 1 gene, copy number 7 (within-gene range 4–7): SCAI.
- chr9:125,146,573–125,707,234, 16 genes, copy number 7 (within-gene range 4–7): PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1, MAPKAP1, RN7SL30P, AL162584.1, HNRNPA1P15.
- chr10:84,081,429–84,518,521, 14 genes, copy number 7 (within-gene range 4–7): HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1.
- chr12:42,069,935–45,992,120, 62 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr16:9,365,540–10,483,638, 17 genes, copy number 7 (within-gene range 5–7): AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2.
- chr18:22,586,465–22,933,764, 4 genes, copy number 7 (within-gene range 5–7): RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2.

Autosomal genes at a single copy (total copy number 1): 1,879. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
